Somatic mutation profile of tumor specimen 0DKRCU from CCDI case PBBYRW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 22.2 years (8,099 days).
Specimen 0DKRCU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42e3a32c-5db3-4e62-8183-8845c9724a62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKRCG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b19ee3de-90f8-4e8b-8ac2-ab2d32ddb531

The open-access MAF lists 48 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 12, 3'UTR 3, Intron 2, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 349/1543 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs869025608, COSV61068581, COSV61070413; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMO | c.1604G>T p.W535L | Missense Mutation (SNP) | VAF 223/967 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs121918347, COSV50824509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACBD5 | c.517+1G>A p.X173_splice | Splice Site (SNP) | VAF 168/2249 reads (7%) | catalogued as rs765884025; called by muse, mutect2
- ASXL1 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 272/1389 reads (20%) | catalogued as COSV100038917; called by muse, mutect2, varscan2
- ATP13A2 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 186/788 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs753087058; ClinVar: uncertain significance; called by muse, varscan2
- CSNK1A1 | c.407A>T p.D136V | Missense Mutation (SNP) | VAF 324/2039 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55796979; called by muse, mutect2, varscan2
- DIAPH1 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 146/1786 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs376981308; called by muse, mutect2
- EPHA2 | c.2869C>T p.R957C | Missense Mutation (SNP) | VAF 111/1049 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs752235979, COSV64454764; called by muse, mutect2, varscan2
- KNCN | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 220/1078 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.884); catalogued as rs762934809; called by muse, mutect2, varscan2
- LILRB5 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 43/542 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); catalogued as rs149797743, COSV100299950; called by muse, mutect2
- MUC16 | c.35944G>A p.G11982S | Missense Mutation (SNP) | VAF 446/917 reads (49%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.517); catalogued as rs1268045083; called by muse, mutect2, varscan2
- MUC16 | c.7072C>T p.R2358W | Missense Mutation (SNP) | VAF 140/528 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs372186047, COSV67485774; called by muse, mutect2, varscan2
- OR10G6 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 36/1380 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs1018339046; called by muse, mutect2
- OR5P2 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 293/1223 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs374622867; called by muse, mutect2, varscan2
- OR9Q2 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 368/1778 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1223295439; called by muse, mutect2, varscan2
- PCDHGB2 | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 187/1159 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV53986548; called by muse, mutect2, varscan2
- SCUBE1 | c.2236G>A p.G746S | Missense Mutation (SNP) | VAF 455/942 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs904493134, COSV62612504; called by muse, mutect2, varscan2
- SLCO1C1 | c.1637G>A p.G546E | Missense Mutation (SNP) | VAF 354/1474 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99860213; called by mutect2, varscan2
- TESPA1 | c.1420C>T p.R474C (on ENST00000316577 / NM_001098815.3; = p.R336C on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 357/1104 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs533904016, COSV57257421; called by muse, mutect2, varscan2
- TUBA3E | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 280/1260 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.387); catalogued as rs781740873, COSV56058855; called by muse, mutect2, varscan2
- TUBGCP2 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 155/1353 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs775339069; called by muse, mutect2, varscan2
- CCT2 | c.671T>A p.I224N | Missense Mutation (SNP) | VAF 325/1229 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DPH7 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 415/1039 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ERICH6B | c.1110C>A p.H370Q | Missense Mutation (SNP) | VAF 315/1600 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLRF1 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 170/828 reads (21%) | called by muse, mutect2, varscan2
- P4HB | c.1108A>G p.K370E | Missense Mutation (SNP) | VAF 488/1102 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PLPP1 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 54/1927 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.023); called by muse, mutect2
- PSMC2 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 970/2260 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PUM1 | c.364dup p.V122Gfs*6 | Frame Shift Ins (INS) | VAF 506/1982 reads (26%) | called by mutect2, varscan2
- THSD7A | c.4356A>C p.E1452D | Missense Mutation (SNP) | VAF 190/2244 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.013); called by muse, mutect2
- ZNF236 | c.950G>T p.S317I | Missense Mutation (SNP) | VAF 595/956 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CCDC186 | c.2590T>C p.L864= | Silent (SNP) | VAF 278/1338 reads (21%) | called by muse, mutect2, varscan2
- CIC | c.1452C>G p.G484= | Silent (SNP) | VAF 126/1448 reads (9%) | catalogued as COSV73907365; called by muse, mutect2
- HEATR3 | c.306G>A p.A102= | Silent (SNP) | VAF 126/638 reads (20%) | catalogued as COSV53531429; called by muse, mutect2, varscan2
- KCNS1 | c.207G>A p.A69= | Silent (SNP) | VAF 82/659 reads (12%) | called by muse, mutect2, varscan2
- KRT85 | c.414C>T p.I138= | Silent (SNP) | VAF 539/977 reads (55%) | catalogued as rs745361591; called by muse, mutect2, varscan2
- NECTIN2 | c.534G>A p.T178= | Silent (SNP) | VAF 155/712 reads (22%) | catalogued as rs758483381; called by muse, mutect2, varscan2
- OR2B11 | c.381C>T p.Y127= | Silent (SNP) | VAF 354/801 reads (44%) | catalogued as rs745312577; called by muse, mutect2, varscan2
- PRR36 | c.3309G>A p.P1103= | Silent (SNP) | VAF 121/539 reads (22%) | called by muse, mutect2, varscan2
- SHANK3 | c.3348G>A p.A1116= | Silent (SNP) | VAF 151/659 reads (23%) | catalogued as rs938021934, COSV53190938; called by muse, mutect2, varscan2
- SLC45A2 | c.798C>T p.Y266= | Silent (SNP) | VAF 457/2140 reads (21%) | catalogued as rs375077956, CM101005, COSV56874260; called by muse, mutect2, varscan2
- TRIM64C | c.48C>T p.C16= | Silent (SNP) | VAF 232/1264 reads (18%) | catalogued as rs755672571; called by muse, mutect2, varscan2
- ZNF222 | c.705G>A p.G235= | Silent (SNP) | VAF 213/890 reads (24%) | called by muse, mutect2, varscan2
- AZI2 | c.647+555C>T | Intron (SNP) | VAF 98/407 reads (24%) | catalogued as rs1203591176; called by muse, mutect2, varscan2
- GZMK | c.*13T>C | 3'UTR (SNP) | VAF 208/1372 reads (15%) | called by muse, mutect2, varscan2
- NPDC1 | c.*33G>A | 3'UTR (SNP) | VAF 67/430 reads (16%) | catalogued as rs761453772, COSV100063915; called by muse, mutect2, varscan2
- TPM4 | c.*520G>A | 3'UTR (SNP) | VAF 109/233 reads (47%) | called by muse, mutect2, varscan2
- USP34 | c.5433+67A>T | Intron (SNP) | VAF 147/541 reads (27%) | called by muse, mutect2, varscan2
